Somatic mutation profile of tumor specimen MMRF_1049_4_BM_CD138pos (aliquot MMRF_1049_4_BM_CD138pos_T1_KHS5U_L13755) from MMRF case MMRF_1049, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,843 days).
Specimen MMRF_1049_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f157cd5-418c-4b95-82d4-c28b8821843f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1049_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1049_1_PB_Whole_C2_KHS5U_K14065; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6fd89e7-5f28-4140-b6e1-6c89c9a058b3

The open-access MAF lists 171 somatic variants for this specimen: 67 protein-altering or splice-affecting, 20 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, 3'UTR 33, Intron 26, Silent 20, 5'UTR 12, RNA 9, Nonsense Mutation 4, 5'Flank 3, Translation Start Site 2, Frame Shift Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1355815263, COSV51402328; called by muse, mutect2, varscan2
- BMP4 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs1258588645; called by muse, mutect2, varscan2
- CDK2AP1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs762855598; called by muse, mutect2, varscan2
- CXCR3 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1362499137; called by muse, mutect2, varscan2
- EGR1 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs199695186; called by muse, varscan2
- ELAVL4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs200396874, COSV100836643; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 205/342 reads (60%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GJD2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51747204; called by muse, mutect2, varscan2
- HKDC1 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100664333; called by muse, mutect2, varscan2
- IGHV2-70 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs779974345; called by muse, mutect2, varscan2
- IGHV4-34 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765275600; called by muse, mutect2
- IGKV4-1 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 85/88 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs368410084; called by muse, mutect2, varscan2
- IGSF9 | c.2296G>A p.A766T (on ENST00000368094 / NM_001135050.2; = p.A750T on NM_020789.4) | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.177); catalogued as rs906876689; called by muse, mutect2, varscan2
- IRS4 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 55/57 reads (96%) | catalogued as COSV100929429; called by muse, mutect2, varscan2
- KCNK3 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1439928866; called by muse, mutect2, varscan2
- KCTD17 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as rs1261369510; called by muse, mutect2, varscan2
- MFSD10 | c.1025C>G p.A342G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.139); catalogued as rs1000503473; called by muse, mutect2, varscan2
- MISP | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV53119921; called by muse, mutect2, varscan2
- NRP2 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.185); catalogued as rs149128054; called by muse, mutect2
- OR4D5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 89/147 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs141977995, COSV100189634; called by muse, mutect2, varscan2
- PCDHGA3 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53951173; called by muse, mutect2, varscan2
- PDE1C | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58504107; called by muse, mutect2
- PLAT | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753993747; called by muse, varscan2
- PP2D1 | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1247260402; called by muse, mutect2
- PRKCD | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 21/383 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57846762; called by muse, mutect2
- SALL3 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750854739; called by muse, mutect2
- SPG11 | c.6338C>G p.S2113C | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99969817; called by muse, mutect2
- SYNGAP1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs574603811; called by muse, mutect2, varscan2
- TSPOAP1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs765140985, COSV52109382; called by muse, mutect2, varscan2
- TTN | c.2227G>A p.A743T (on ENST00000591111; = p.A697T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/141 reads (10%) | PolyPhen benign (0.001); catalogued as rs370728359; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZFP57 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs564988086; called by muse, mutect2, varscan2
- ZNF223 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 80/386 reads (21%) | catalogued as COSV71571828; called by muse, mutect2, varscan2
- AFTPH | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 106/508 reads (21%) | called by muse, mutect2, varscan2
- AP4B1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- B3GALNT1 | c.475del p.T159Pfs*8 | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | called by mutect2, pindel, varscan2
- CCDC186 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCNC | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CNGA2 | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 115/116 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPSF1 | c.215T>A p.F72Y | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- CWH43 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HDHD2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSPD1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGBP1P2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 91/150 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHV2-70 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- IGHV2-70D | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAG1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); called by muse, varscan2
- LIAS | c.138A>T p.Q46H | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MEP1A | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MNT | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NETO1 | c.*14G>C | Splice Region (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- OR2T29 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 97/389 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2T5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- PCDH15 | c.4289C>A p.A1430E | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PRDM9 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PRMT8 | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN22 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RAB3A | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RASGRF2 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 100/405 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RPL10 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SHANK1 | c.2872T>A p.S958T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.05); called by muse, mutect2
- SLC18A3 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT5H | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TENT5C | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM1 | c.509-2A>T p.X170_splice | Splice Site (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- TMEM26 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRBV6-8 | c.112A>C p.M38L | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ABCA1 | c.6765A>G p.K2255= | Silent (SNP) | VAF 147/449 reads (33%) | called by muse, mutect2, varscan2
- ABCA7 | c.4875G>C p.L1625= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as rs754027385; called by muse, mutect2, varscan2
- ADAMTS5 | c.984G>A p.L328= | Silent (SNP) | VAF 62/371 reads (17%) | catalogued as rs760808495; called by muse, mutect2, varscan2
- AKR7L | c.114C>T p.R38= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1407149194; called by muse, mutect2, varscan2
- BTBD1 | c.966A>G p.R322= | Silent (SNP) | VAF 83/458 reads (18%) | called by muse, mutect2, varscan2
- CCKBR | c.21C>T p.N7= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- FOXD3 | c.1179C>T p.G393= | Silent (SNP) | VAF 72/129 reads (56%) | catalogued as rs929422083; called by muse, mutect2, varscan2
- IGHV2-70D | c.358C>G p.*120= | Silent (SNP) | VAF 24/29 reads (83%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.69G>C p.L23= | Silent (SNP) | VAF 39/80 reads (49%) | called by muse, varscan2
- LOXHD1 | c.57C>T p.Y19= | Silent (SNP) | VAF 61/142 reads (43%) | called by muse, mutect2, varscan2
- LTB4R2 | c.283C>T p.L95= (on ENST00000528054; = p.L64= on NM_019839.5) | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- METTL11B | c.375C>T p.S125= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1456074952, COSV63030163; called by muse, mutect2
- MSH3 | c.984G>T p.R328= | Silent (SNP) | VAF 53/766 reads (7%) | called by muse, mutect2
- MYO15A | c.1989G>A p.P663= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- MYO9B | c.3942G>C p.R1314= | Silent (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2
- PIWIL4 | c.2247C>T p.N749= | Silent (SNP) | VAF 103/324 reads (32%) | catalogued as rs756931190; called by muse, mutect2, varscan2
- RIPK4 | c.177C>T p.D59= | Silent (SNP) | VAF 54/300 reads (18%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1101C>A p.G367= | Silent (SNP) | VAF 22/507 reads (4%) | called by muse, mutect2
- TNS3 | c.2787C>A p.T929= | Silent (SNP) | VAF 43/147 reads (29%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.408C>T p.R136= | Silent (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- AC020765.6 | c.-42G>A | 5'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- AC104078.1 | n.1505A>G | RNA (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- ANKH | c.*4608C>T | 3'UTR (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- ARRB1 | c.21-16545C>T | Intron (SNP) | VAF 37/410 reads (9%) | called by muse, mutect2
- ATP6V0E2 | chr7:149873497 G>T | 5'Flank (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.950G>T | RNA (SNP) | VAF 190/1034 reads (18%) | called by muse, mutect2
- C9orf57 | c.*2T>C | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- CCN2 | c.*785T>C | 3'UTR (SNP) | VAF 31/129 reads (24%) | catalogued as rs867008423; called by muse, mutect2, varscan2
- CDH6 | c.*637A>G | 3'UTR (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- CYP3A7 | c.670+133A>G | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- DEFB134 | chr8:11993557 A>T | 3'Flank (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- DLX6 | c.-246C>G | 5'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- EYS | c.862+45A>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- FAM171A1 | c.*814G>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- FAM217B | c.*1232T>A | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- FASTKD2 | c.2013+14G>A | Intron (SNP) | VAF 49/147 reads (33%) | catalogued as COSV52700286; called by muse, mutect2, varscan2
- FASTKD2 | c.2013+15C>T | Intron (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- FGD2 | c.1459-105C>T | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- FLCN | c.-24-703_-24-693del | Intron (DEL) | VAF 35/62 reads (56%) | called by mutect2, pindel, varscan2
- FOXK1 | c.*6792G>A | 3'UTR (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- FOXK2 | c.*322G>T | 3'UTR (SNP) | VAF 58/99 reads (59%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+4543C>T | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035862 G>A | 5'Flank (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- GBX2 | c.-401C>T | 5'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- GOLGA7B | c.*1762T>C | 3'UTR (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- GRIN1 | c.2589+66C>T | Intron (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- IBA57 | c.*493G>A | 3'UTR (SNP) | VAF 96/175 reads (55%) | catalogued as rs941484757; called by muse, mutect2, varscan2
- INTS11 | c.429+196C>T | Intron (SNP) | VAF 73/138 reads (53%) | catalogued as rs755105272; called by muse, mutect2, varscan2
- INTS4P2 | n.1230G>C | RNA (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- ITGA9 | c.2154+54C>A | Intron (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2
- KIF1A | c.*3162C>A | 3'UTR (SNP) | VAF 57/173 reads (33%) | called by muse, mutect2, varscan2
- KIFC3 | c.172+79C>T | Intron (SNP) | VAF 26/45 reads (58%) | called by muse, mutect2, varscan2
- KLF12 | c.*1496G>A | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- KLRF1 | c.-50T>C | 5'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, varscan2
- KMT5B | c.*1329A>T | 3'UTR (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2, varscan2
- KRIT1 | c.486-78_486-77del | Intron (DEL) | VAF 82/162 reads (51%) | called by pindel, varscan2
- LINC01460 | n.224G>T | RNA (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- LINC02692 | n.828G>T | RNA (SNP) | VAF 51/85 reads (60%) | called by muse, mutect2, varscan2
- LMO7 | c.1026-23A>C | Intron (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- LTBP1 | c.-179T>G | 5'UTR (SNP) | VAF 112/173 reads (65%) | called by muse, mutect2, varscan2
- LYSMD2 | c.*131C>T | 3'UTR (SNP) | VAF 75/161 reads (47%) | called by muse, mutect2, varscan2
- MAGI2 | c.-3G>A | 5'UTR (SNP) | VAF 165/238 reads (69%) | catalogued as rs759941427; called by muse, mutect2, varscan2
- MMS22L | c.607-321G>A | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as rs536379694; called by muse, mutect2, varscan2
- MRGPRX10P | n.245C>T | RNA (SNP) | VAF 41/118 reads (35%) | catalogued as rs1007764171; called by muse, mutect2, varscan2
- MRGPRX10P | n.75A>G | RNA (SNP) | VAF 51/213 reads (24%) | called by muse, mutect2, varscan2
- MYRIP | c.-21C>T | 5'UTR (SNP) | VAF 110/343 reads (32%) | called by muse, mutect2, varscan2
- NASPP1 | n.1035G>C | RNA (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- NDUFS7 | c.544+726G>C | Intron (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- NECAP1 | c.*1175T>C | 3'UTR (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- NR2F1 | c.-678C>T | 5'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- NRXN1 | c.-843A>T | 5'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- NUDT4 | c.*8387T>A | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- NUP160 | c.*981T>G | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, varscan2
- NUP160 | c.*922T>G | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, varscan2
- OCM2 | c.-60T>A | 5'UTR (SNP) | VAF 162/540 reads (30%) | called by muse, mutect2, varscan2
- OR5M4P | n.433T>A | RNA (SNP) | VAF 63/94 reads (67%) | called by muse, mutect2, varscan2
- PCGF5 | c.*1981T>G | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- PDE10A | c.2268-150C>G | Intron (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- PDE8A | c.*1185A>T | 3'UTR (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- PDGFRB | c.*676C>T | 3'UTR (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-67C>T | Intron (SNP) | VAF 59/92 reads (64%) | called by muse, mutect2, varscan2
- PTCHD4 | c.908-20624_908-20623del | Intron (DEL) | VAF 8/78 reads (10%) | called by pindel, varscan2
- PTGER2 | c.*389C>A | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- RASA3 | c.*352A>G | 3'UTR (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- RFX3 | c.*2910G>A | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- RINL | c.1342+83G>C | Intron (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- RND1 | c.*586T>G | 3'UTR (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- RNF123 | c.2674+387T>C | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- RRP15 | c.*5095C>T | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, varscan2
- SEC16B | c.999-84T>C | Intron (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- SH2B3 | c.*635C>T | 3'UTR (SNP) | VAF 66/126 reads (52%) | called by muse, mutect2, varscan2
- SLC38A10 | c.-243G>A | 5'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6613_441-6612del | Intron (DEL) | VAF 38/141 reads (27%) | catalogued as rs1376814459; called by mutect2, pindel, varscan2
- SP8 | c.-233A>G | 5'UTR (SNP) | VAF 111/373 reads (30%) | called by muse, mutect2, varscan2
- SPRY4 | c.*14A>T | 3'UTR (SNP) | VAF 32/373 reads (9%) | called by muse, mutect2
- SSBP3 | c.*410C>T | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.*507A>G | 3'UTR (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2
- TMEM170A | c.*4274A>G | 3'UTR (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- TMEM192 | c.*3278C>T | 3'UTR (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- TRA2B | c.37-70C>G | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- TRAV22 | chr14:22066251 G>A | 5'Flank (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2127G>A | Intron (SNP) | VAF 92/408 reads (23%) | catalogued as rs906476505; called by muse, mutect2, varscan2
- TTLL5 | c.740+1680G>A | Intron (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- WNT2B | c.*497C>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | catalogued as rs918441591; called by muse, mutect2, varscan2
